Somatic mutation profile of tumor specimen MMRF_2793_1_BM_CD138pos (aliquot MMRF_2793_1_BM_CD138pos_T1_KHS5U_L15734) from MMRF case MMRF_2793, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.2 years (21,638 days).
Specimen MMRF_2793_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97928b4b-efda-40a6-885d-7bcc08d9f593.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2793_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2793_1_PB_WBC_C3_KHS5U_L15778; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78c31b6d-7588-491c-a6b8-a9fc0afbaf3a

The open-access MAF lists 115 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 33, Intron 12, Silent 10, Nonsense Mutation 5, 5'UTR 3, 5'Flank 3, 3'Flank 3, Frame Shift Del 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199551851, COSV55945290, COSV55947749; called by muse, mutect2, varscan2
- ARID3A | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV55046024; called by muse, mutect2, varscan2
- CD93 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.779); catalogued as COSV55666727; called by mutect2, varscan2
- CDH23 | c.9128G>A p.R3043Q | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs565784910, COSV56447789; called by muse, mutect2, varscan2
- CNTNAP5 | c.976T>G p.F326V | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70473679; called by muse, mutect2, varscan2
- CSMD1 | c.7073A>G p.Y2358C (on ENST00000520002; = p.Y2357C on NM_033225.6) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV59281181; called by muse, mutect2, varscan2
- DDX5 | c.767T>A p.M256K | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555671437; called by muse, mutect2, varscan2
- DDX58 | c.2315A>G p.D772G | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1032064406; called by muse, mutect2, varscan2
- ESR2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs145278854; called by muse, mutect2, varscan2
- GGT6 | c.1016C>T p.P339L (on ENST00000574154 / NM_001122890.3; = p.P307L on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs753458526; called by muse, mutect2, varscan2
- IGLV3-1 | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs367981147; called by muse, varscan2
- ITGA7 | c.2995G>A p.A999T (on ENST00000555728; = p.A955T on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs182485135, COSV99144353; called by muse, mutect2, varscan2
- NWD1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs375674809; called by muse, mutect2, varscan2
- OR5T3 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1217327222; called by muse, mutect2, varscan2
- PHIP | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs1323492967; called by mutect2, varscan2
- PNLIPRP2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs370305442, COSV100077562; called by muse, mutect2, varscan2
- TEX26 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1157272367, COSV66839384; called by muse, mutect2, varscan2
- TGS1 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.541); catalogued as COSV52699262; called by muse, mutect2, varscan2
- TSPAN8 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.712); catalogued as COSV56077425; called by muse, varscan2
- ZSWIM6 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs963100061; called by muse, mutect2
- ABCA12 | c.6528C>A p.Y2176* (on ENST00000272895 / NM_173076.3; = p.Y1858* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 49/235 reads (21%) | called by muse, mutect2, varscan2
- ALS2CL | c.872A>G p.E291G | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BOC | c.669C>T p.R223= | Splice Region (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2
- CSHL1 | c.70G>C p.A24P | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DLX5 | c.739T>C p.S247P | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF2B1 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBN1 | c.571A>C p.S191R | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FOXL1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- GLS | c.1336A>T p.R446* | Nonsense Mutation (SNP) | VAF 56/248 reads (23%) | called by muse, mutect2, varscan2
- GRM7 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNC3 | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K3 | c.196A>T p.T66S (on ENST00000342679 / NM_145109.3; = p.T37S on NM_002756.4) | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, varscan2
- NIPBL | c.5546A>G p.Y1849C | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKRF | c.1984A>G p.R662G | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NPAP1 | c.59_60delinsT p.P20Lfs*95 | Frame Shift Del (DEL) | VAF 54/188 reads (29%) | called by pindel, varscan2*
- OGFOD2 | c.887G>C p.G296A (on ENST00000228922 / NM_001304833.1; = p.G236A on NM_024623.3) | Missense Mutation (SNP) | VAF 53/296 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEBP4 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- PHF2 | c.1400G>C p.R467P | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, varscan2
- PITPNA | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 77/289 reads (27%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1055G>C p.G352A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- PKHD1 | c.8423G>T p.G2808V | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPM1B | c.189del p.G64Dfs*13 | Frame Shift Del (DEL) | VAF 81/316 reads (26%) | called by mutect2, pindel, varscan2
- PRPF40A | c.614G>A p.W205* | Nonsense Mutation (SNP) | VAF 26/227 reads (11%) | called by muse, mutect2, varscan2
- RGS12 | c.3629G>A p.R1210K | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- SERINC1 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TACC1 | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, varscan2
- ZIC3 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0.402); called by muse, varscan2
- ZNF717 | c.1515A>C p.K505N | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF783 | c.627G>C p.E209D | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- ARHGEF40 | c.624A>C p.G208= | Silent (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- BCAM | c.552G>A p.T184= | Silent (SNP) | VAF 37/223 reads (17%) | catalogued as rs575984275, COSV54305140; called by muse, mutect2, varscan2
- GYS1 | c.2139G>A p.T713= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs745510608; called by muse, mutect2, varscan2
- LINS1 | c.975G>A p.P325= | Silent (SNP) | VAF 58/266 reads (22%) | catalogued as rs377267845; called by muse, mutect2, varscan2
- LRRIQ4 | c.762C>T p.A254= | Silent (SNP) | VAF 80/378 reads (21%) | catalogued as rs760741011, COSV61618771; called by muse, mutect2, varscan2
- PIK3R4 | c.4056G>A p.G1352= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs201481225; called by muse, mutect2, varscan2
- QRFPR | c.978C>T p.I326= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs775852043; called by muse, mutect2, varscan2
- RANBP2 | c.8412T>C p.S2804= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- RNF103 | c.84T>C p.Y28= | Silent (SNP) | VAF 47/178 reads (26%) | catalogued as rs769086460; called by muse, mutect2, varscan2
- SALL3 | c.429C>T p.R143= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1467425547, COSV73306407; called by muse, mutect2, varscan2
- ADGRF1 | c.611+258G>A | Intron (SNP) | VAF 4/52 reads (8%) | catalogued as rs1487296175; called by muse, mutect2
- ALDH1A3 | c.537+124C>T | Intron (SNP) | VAF 9/31 reads (29%) | catalogued as rs1463384263; called by muse, mutect2
- ANKMY2 | c.1012-1057C>A | Intron (SNP) | VAF 12/62 reads (19%) | catalogued as COSV61013282; called by mutect2, varscan2
- ARHGEF18 | c.*161_*168del | 3'UTR (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel
- BARX2 | c.*198A>C | 3'UTR (SNP) | VAF 83/151 reads (55%) | called by muse, mutect2, varscan2
- BTLA | c.*1765C>A | 3'UTR (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- CACNB4 | c.*1490T>A | 3'UTR (SNP) | VAF 7/87 reads (8%) | catalogued as rs1396555430, COSV52397389; called by muse, mutect2
- CCDC57 | c.2564-5690C>T | Intron (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- CETN3 | c.-59C>T | 5'UTR (SNP) | VAF 75/473 reads (16%) | called by muse, mutect2, varscan2
- CNTROB | c.438-13C>G | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- CSMD1 | chr8:2935573 G>A | 3'Flank (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- DCHS2 | n.6399A>G | RNA (SNP) | VAF 56/310 reads (18%) | called by muse, mutect2, varscan2
- DOCK4 | c.3401+133G>A | Intron (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- EEF1AKMT3 | c.*842C>G | 3'UTR (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- EMC2 | chr8:108443603 G>A | 5'Flank (SNP) | VAF 53/165 reads (32%) | called by muse, varscan2
- ESRRG | c.*3207G>A | 3'UTR (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- FBXL7 | c.*1513G>A | 3'UTR (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- GIPC1 | c.*43G>A | 3'UTR (SNP) | VAF 6/25 reads (24%) | catalogued as rs934660572; called by muse, mutect2
- GLI4 | c.125-53C>T | Intron (SNP) | VAF 28/64 reads (44%) | catalogued as rs1026889768; called by muse, mutect2, varscan2
- GSE1 | c.*2038C>T | 3'UTR (SNP) | VAF 41/139 reads (29%) | catalogued as rs951240450; called by muse, mutect2, varscan2
- HTR1F | c.*357T>G | 3'UTR (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- IGLV4-3 | c.*2C>T | 3'UTR (SNP) | VAF 19/96 reads (20%) | catalogued as rs550223397; called by muse, mutect2, varscan2
- ITPR1 | c.*591G>A | 3'UTR (SNP) | VAF 30/134 reads (22%) | called by muse, varscan2
- KRT32 | c.*305C>G | 3'UTR (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2
- LRRC49 | chr15:70892572 C>T | 5'Flank (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- MACC1 | c.*207T>A | 3'UTR (SNP) | VAF 15/75 reads (20%) | catalogued as COSV60545563; called by muse, mutect2, varscan2
- MAEL | c.*148A>T | 3'UTR (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- MYH16 | n.2462G>T | RNA (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- MYO1B | c.*438A>C | 3'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- NFKBIA | c.*394A>G | 3'UTR (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- NICN1 | c.*1341G>A | 3'UTR (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- NPLOC4 | c.1669+43C>T | Intron (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- NRXN1 | c.832+2194A>G | Intron (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | chr9:110169539 G>A | 3'Flank (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- PAXIP1 | c.325-2840A>T | Intron (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- PKNOX2 | c.*1303C>T | 3'UTR (SNP) | VAF 99/174 reads (57%) | called by muse, mutect2, varscan2
- POLR3D | c.*346G>A | 3'UTR (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- PRIMA1 | c.*1868T>A | 3'UTR (SNP) | VAF 52/168 reads (31%) | called by muse, mutect2, varscan2
- RAP2B | c.*835G>T | 3'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- SHOX2 | chr3:158106260 G>A | 5'Flank (SNP) | VAF 12/66 reads (18%) | catalogued as rs1326045794; called by mutect2, varscan2
- SLCO1A2 | c.*3849T>A | 3'UTR (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.*607_*610del | 3'UTR (DEL) | VAF 16/77 reads (21%) | catalogued as rs1216479976; called by mutect2, pindel, varscan2
- STOML1 | c.-44A>C | 5'UTR (SNP) | VAF 24/106 reads (23%) | called by muse, varscan2
- THSD7B | c.*647G>A | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- TMTC1 | c.*4711G>C | 3'UTR (SNP) | VAF 30/146 reads (21%) | called by muse, mutect2
- TRIB1 | c.*1712A>G | 3'UTR (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- TRIB1 | c.*1713G>C | 3'UTR (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- TRIM24 | c.*2892G>A | 3'UTR (SNP) | VAF 27/178 reads (15%) | catalogued as rs894751976; called by muse, mutect2, varscan2
- TRIM46 | c.*732G>T | 3'UTR (SNP) | VAF 13/88 reads (15%) | called by mutect2, varscan2
- TRNT1 | c.-17G>T | 5'UTR (SNP) | VAF 41/330 reads (12%) | called by muse, mutect2, varscan2
- TUBA5P | n.382+730G>A | Intron (SNP) | VAF 39/113 reads (35%) | catalogued as rs928936574; called by muse, mutect2, varscan2
- TUT1 | chr11:62574000 G>T | 3'Flank (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- TWNK | c.*803A>C | 3'UTR (SNP) | VAF 12/45 reads (27%) | called by muse, varscan2
- TYRO3 | c.*496G>A | 3'UTR (SNP) | VAF 56/238 reads (24%) | called by muse, mutect2, varscan2
- UCHL1 | c.*108C>T | 3'UTR (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- UCKL1 | c.924-211G>A | Intron (SNP) | VAF 51/213 reads (24%) | called by muse, mutect2, varscan2
